Somatic mutation profile of tumor specimen C3N-01752-02 (aliquot CPT0162940006) from CPTAC case C3N-01752, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 73.2 years (26,753 days).
Specimen C3N-01752-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 963b42ef-315f-4371-ac65-79d2995bf5c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01752-31 (Blood Derived Normal), aliquot CPT0162970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/574a6b96-fdbb-4292-8d1a-70a74afe389b

The open-access MAF lists 154 somatic variants for this specimen: 95 protein-altering or splice-affecting, 42 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 42, Intron 7, RNA 7, Nonsense Mutation 3, Frame Shift Ins 3, 3'UTR 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 175/213 reads (82%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM1 | c.1090A>T p.I364F | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs779355608; called by muse, mutect2, varscan2
- ACSM4 | c.1504G>C p.V502L | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV68067688; called by muse, mutect2, varscan2
- ANK1 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 208/571 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1435310605; called by muse, mutect2, varscan2
- ATP6V1FNB | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs547097835, COSV99925759; called by muse, varscan2
- BMP2 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs755006479; called by muse, mutect2, varscan2
- CALCR | c.1294C>A p.R432S (on ENST00000649521 / NM_001164737.2; = p.R416S on NM_001742.4) | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.132); catalogued as rs766603297; called by muse, mutect2, varscan2
- CNOT1 | c.4865A>G p.H1622R | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs1043108412; called by muse, mutect2, varscan2
- DNAH1 | c.4669A>G p.T1557A | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101325899; called by muse, mutect2, varscan2
- FBF1 | c.3130C>T p.R1044* (on ENST00000586717; = p.R1059* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 93/287 reads (32%) | catalogued as rs1414757080, COSV100045619; called by muse, mutect2, varscan2
- FLG | c.6589G>C p.E2197Q | Missense Mutation (SNP) | VAF 114/294 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV64239913; called by muse, mutect2, varscan2
- GON4L | c.2191A>G p.T731A | Missense Mutation (SNP) | VAF 105/304 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as rs1307933065; called by muse, mutect2, varscan2
- GPRASP1 | c.3665G>T p.R1222L | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as COSV64356215; called by muse, mutect2, varscan2
- HSPA6 | c.1858G>T p.G620W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as COSV59062025; called by muse, mutect2, varscan2
- ITGB4 | c.3298A>T p.I1100F | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV52321604; called by muse, mutect2, varscan2
- KCTD16 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 250/345 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745350480, COSV72578069; called by muse, mutect2, varscan2
- KLHDC2 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.95); catalogued as COSV100027089; called by muse, mutect2, varscan2
- KNDC1 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs755705832, COSV58833030; called by muse, mutect2, varscan2
- KRT79 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs145046939; called by muse, mutect2
- LCE2D | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 126/374 reads (34%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.02); catalogued as rs1557801199; called by muse, mutect2, varscan2
- LLGL1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 157/458 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs761027899; called by muse, mutect2, varscan2
- LRRTM1 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 81/412 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV54445731; called by muse, mutect2, varscan2
- LUC7L3 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370919781; called by muse, mutect2, varscan2
- NSMCE1 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs769578125; called by muse, mutect2, varscan2
- OR14A16 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs754553727, COSV62926722; called by muse, mutect2, varscan2
- OR5M8 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV59115639; called by muse, mutect2, varscan2
- PGBD2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs151078940; called by muse, mutect2, varscan2
- PLEKHG4B | c.2926T>C p.F976L (on ENST00000283426; = p.F1332L on NM_052909.5) | Missense Mutation (SNP) | VAF 348/518 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1180145354; called by muse, mutect2, varscan2
- PTCH2 | c.2989G>A p.A997T | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); catalogued as COSV100942286; called by muse, mutect2, varscan2
- RIOK3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200387789; called by muse, mutect2, varscan2
- SIRT1 | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.557); catalogued as rs757140711; called by muse, mutect2
- SMPD3 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1397138375, COSV54711146; called by muse, mutect2, varscan2
- SON | c.2161A>G p.M721V | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.867); catalogued as rs1236773493; called by muse, mutect2, varscan2
- SPAG17 | c.2619G>A p.M873I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV60459056; called by muse, mutect2, varscan2
- STX19 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs765373320; called by muse, mutect2, varscan2
- TM9SF4 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs753161371; called by muse, mutect2, varscan2
- TMEM61 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 120/319 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs200736187, COSV64873323; called by muse, mutect2, varscan2
- UBR5 | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as COSV99642211; called by muse, mutect2
- ABCC1 | c.4586G>T p.G1529V | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- AGBL5 | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ANKRD26 | c.5018C>A p.S1673Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ARID3A | c.386A>T p.E129V | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); called by muse, varscan2
- ASPM | c.6766A>G p.R2256G | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ATP12A | c.1102A>C p.K368Q | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCL9L | c.3386C>A p.P1129Q | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- CDH13 | c.1897A>C p.K633Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CEP135 | c.2040dup p.D681* | Frame Shift Ins (INS) | VAF 62/189 reads (33%) | called by mutect2, pindel, varscan2
- COL4A4 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPED1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DHX8 | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DNAH11 | c.1099A>T p.T367S | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- DNAH6 | c.7435T>C p.Y2479H | Missense Mutation (SNP) | VAF 142/280 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- EMILIN2 | c.1484A>T p.Q495L | Missense Mutation (SNP) | VAF 70/510 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM214A | c.2626C>T p.L876F | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- FMO4 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- FSIP2 | c.4814G>A p.G1605D | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GAS1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 303/402 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- GNB2 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 119/396 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- GOLGA8A | c.337A>T p.I113F (on ENST00000432566; = p.I85F on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by mutect2, varscan2
- GREM2 | c.152A>T p.E51V | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- IGKV3-11 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 201/415 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- IGSF3 | c.2091del p.Q698Sfs*2 (on ENST00000369486 / NM_001007237.3; = p.Q718Sfs*2 on NM_001542.4) | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | called by mutect2, pindel, varscan2
- KLHL1 | c.2171C>G p.T724S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- LIG4 | c.2661A>T p.K887N | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- LRIG3 | c.878A>T p.H293L | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- LRRC32 | c.463T>C p.S155P | Missense Mutation (SNP) | VAF 97/346 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LTBP4 | c.670G>T p.V224L (on ENST00000308370 / NM_001042544.1; = p.V187L on NM_003573.2) | Missense Mutation (SNP) | VAF 196/563 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LZTS3 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 214/658 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- MRPS14 | c.383G>C p.W128S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NAV2 | c.5434C>G p.H1812D (on ENST00000396087 / NM_001244963.2; = p.H1756D on NM_145117.5) | Missense Mutation (SNP) | VAF 87/580 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NCBP2 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP14 | c.2697C>A p.N899K | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NOTCH2 | c.4802A>G p.K1601R | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOVA1 | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 173/365 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- OSBP2 | c.900C>A p.S300R | Missense Mutation (SNP) | VAF 399/541 reads (74%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- OVCH1 | c.1516A>G p.S506G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PHF2 | c.2036A>T p.Y679F | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.97); called by muse, mutect2
- PRAMEF1 | c.677G>T p.C226F | Missense Mutation (SNP) | VAF 255/347 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PTPN22 | c.106A>T p.T36S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PURB | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RALGDS | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RBM38 | c.602G>C p.S201T | Missense Mutation (SNP) | VAF 221/602 reads (37%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- REG3G | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- RYR1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 176/487 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCART1 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- SIM1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SYT10 | c.214T>A p.S72T | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- TENT4A | c.1508T>C p.V503A | Missense Mutation (SNP) | VAF 200/290 reads (69%) | SIFT tolerated (0.49); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- TTN | c.39892C>G p.P13298A (on ENST00000591111; = p.P5874A on NM_003319.4) | Missense Mutation (SNP) | VAF 49/128 reads (38%) | PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- UHRF1BP1L | c.3109A>G p.S1037G | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR33 | c.3193dup p.D1065Gfs*21 | Frame Shift Ins (INS) | VAF 52/203 reads (26%) | called by mutect2, pindel, varscan2
- ZNF133 | c.1804G>A p.G602R (on ENST00000316358 / NM_001352454.2; = p.G601R on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ZNF714 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 45/132 reads (34%) | called by muse, mutect2, varscan2
- ZNF808 | c.401dup p.L135Vfs*4 | Frame Shift Ins (INS) | VAF 29/87 reads (33%) | called by mutect2, pindel, varscan2
- ZZEF1 | c.4444C>A p.P1482T | Missense Mutation (SNP) | VAF 183/236 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM28 | c.714C>A p.V238= | Silent (SNP) | VAF 36/115 reads (31%) | called by muse, mutect2, varscan2
- CD69 | c.21C>T p.F7= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs747988312; called by muse, mutect2, varscan2
- CDRT1 | c.501C>A p.I167= | Silent (SNP) | VAF 44/128 reads (34%) | called by muse, mutect2, varscan2
- COL22A1 | c.480C>T p.D160= | Silent (SNP) | VAF 68/183 reads (37%) | catalogued as rs1220903304, COSV57339352, COSV57348952; called by muse, mutect2, varscan2
- DCAF1 | c.1791G>A p.V597= | Silent (SNP) | VAF 21/33 reads (64%) | called by muse, mutect2, varscan2
- DOCK7 | c.3489G>A p.T1163= (on ENST00000635253 / NM_001367561.1; = p.T1132= on NM_033407.3) | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs761488679, COSV52005184; called by muse, mutect2, varscan2
- EEF1B2 | c.51T>C p.D17= | Silent (SNP) | VAF 69/195 reads (35%) | called by muse, mutect2, varscan2
- FHOD3 | c.132G>A p.A44= | Silent (SNP) | VAF 126/193 reads (65%) | catalogued as rs1310969125; called by muse, mutect2, varscan2
- FLG | c.2172C>T p.G724= | Silent (SNP) | VAF 206/558 reads (37%) | catalogued as rs756276659; called by muse, varscan2
- FRYL | c.549G>C p.V183= | Silent (SNP) | VAF 47/134 reads (35%) | called by muse, mutect2, varscan2
- HRNR | c.2394A>C p.T798= | Silent (SNP) | VAF 105/275 reads (38%) | called by muse, mutect2, varscan2
- IGHG4 | c.132C>T p.G44= | Silent (SNP) | VAF 166/573 reads (29%) | catalogued as rs755927718; called by mutect2, varscan2
- ITGA11 | c.1443G>C p.G481= | Silent (SNP) | VAF 79/260 reads (30%) | called by muse, mutect2, varscan2
- IVL | c.1650C>T p.G550= | Silent (SNP) | VAF 89/311 reads (29%) | catalogued as rs1203941177; called by muse, mutect2, varscan2
- KCNIP3 | c.600C>T p.R200= | Silent (SNP) | VAF 50/168 reads (30%) | catalogued as COSV54671647; called by muse, mutect2, varscan2
- KHDRBS3 | c.879C>T p.T293= | Silent (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- KIF13A | c.2283A>G p.E761= | Silent (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.531C>T p.V177= | Silent (SNP) | VAF 147/425 reads (35%) | catalogued as rs1300179741; called by muse, mutect2, varscan2
- LIPN | c.951A>G p.K317= | Silent (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- LTBP1 | c.1131G>T p.G377= (on ENST00000404816 / NM_206943.4; = p.G51= on NM_000627.4) | Silent (SNP) | VAF 104/206 reads (50%) | called by muse, mutect2, varscan2
- MATN2 | c.2631T>C p.N877= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs1468286933; called by muse, mutect2, varscan2
- MEGF11 | c.1710C>T p.R570= | Silent (SNP) | VAF 103/423 reads (24%) | called by muse, mutect2, varscan2
- MEGF8 | c.2268G>A p.R756= | Silent (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- NCAPG2 | c.933T>C p.S311= | Silent (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- NCBP2 | c.354C>T p.G118= | Silent (SNP) | VAF 81/257 reads (32%) | called by muse, mutect2, varscan2
- NEGR1 | c.75C>T p.C25= | Silent (SNP) | VAF 100/315 reads (32%) | called by muse, mutect2, varscan2
- P4HA1 | c.987G>A p.E329= | Silent (SNP) | VAF 43/198 reads (22%) | called by muse, mutect2, varscan2
- PLD4 | c.192G>A p.Q64= | Silent (SNP) | VAF 104/448 reads (23%) | called by muse, mutect2, varscan2
- PROB1 | c.643C>A p.R215= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as COSV56171594; called by muse, mutect2, varscan2
- PRR27 | c.615C>T p.A205= | Silent (SNP) | VAF 42/181 reads (23%) | catalogued as rs1268413615, COSV60640030; called by muse, mutect2, varscan2
- RASA3 | c.423G>A p.G141= | Silent (SNP) | VAF 120/408 reads (29%) | catalogued as rs1443190193; called by muse, mutect2, varscan2
- SAGE1 | c.306A>G p.P102= | Silent (SNP) | VAF 45/56 reads (80%) | catalogued as rs782576407; called by muse, mutect2, varscan2
- SAMD5 | c.258C>T p.P86= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as rs1341782109; called by muse, mutect2, varscan2
- SEMA5B | c.789C>T p.Y263= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs867213556; called by muse, mutect2, varscan2
- SFXN5 | c.502C>T p.L168= | Silent (SNP) | VAF 146/293 reads (50%) | catalogued as rs747126165; called by muse, mutect2, varscan2
- SH3GL1 | c.300C>T p.H100= | Silent (SNP) | VAF 227/595 reads (38%) | catalogued as rs777405786; called by muse, mutect2, varscan2
- SRCIN1 | c.1287C>T p.L429= (on ENST00000621492; = p.L395= on NM_025248.3) | Silent (SNP) | VAF 107/288 reads (37%) | called by muse, mutect2, varscan2
- STAT3 | c.414G>A p.T138= | Silent (SNP) | VAF 137/431 reads (32%) | catalogued as rs765452694; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNK1 | c.1254C>T p.D418= (on ENST00000576812 / NM_001251902.2; = p.D413= on NM_003985.5) | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs371780248; called by muse, mutect2, varscan2
- WWC2 | c.726G>A p.L242= | Silent (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- ZNF592 | c.1968C>A p.I656= | Silent (SNP) | VAF 522/990 reads (53%) | catalogued as COSV100246089; called by muse, mutect2, varscan2
- ZNF91 | c.2979C>T p.P993= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as COSV56082470; called by muse, mutect2, varscan2
- ACTG1 | c.*98C>G | 3'UTR (SNP) | VAF 16/186 reads (9%) | catalogued as rs1340147087; called by muse, mutect2
- ADGRG5 | n.471T>G | RNA (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- AGAP12P | n.768C>G | RNA (SNP) | VAF 192/612 reads (31%) | called by muse, mutect2, varscan2
- ALKBH3 | c.460-4294A>C | Intron (SNP) | VAF 64/184 reads (35%) | called by muse, mutect2, varscan2
- ATP5IF1 | c.180-52C>G | Intron (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- DDX55 | c.1165-304C>G | Intron (SNP) | VAF 67/210 reads (32%) | called by muse, mutect2, varscan2
- EFHC1 | c.*2532G>A | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18730A>G | Intron (SNP) | VAF 14/58 reads (24%) | catalogued as rs1320002622; called by muse, mutect2, varscan2
- LINC02520 | n.505G>T | RNA (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- LINC02740 | n.259G>T | RNA (SNP) | VAF 56/288 reads (19%) | called by muse, mutect2, varscan2
- LINC02876 | n.420C>T | RNA (SNP) | VAF 18/42 reads (43%) | catalogued as rs746872255; called by muse, mutect2
- LRRC37A5P | n.350C>T | RNA (SNP) | VAF 132/350 reads (38%) | catalogued as rs551973551; called by muse, mutect2, varscan2
- MRPL45P2 | n.355G>A | RNA (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- NALCN | c.2193-5361A>T | Intron (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- SRRM2 | c.8022-516G>T | Intron (SNP) | VAF 58/138 reads (42%) | called by muse, mutect2, varscan2
- VASH1 | c.*329G>A | 3'UTR (SNP) | VAF 308/547 reads (56%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3579C>T | Intron (SNP) | VAF 86/225 reads (38%) | catalogued as rs1183875399; called by muse, mutect2, varscan2
